Somatic mutation profile of tumor specimen TCGA-CJ-6032-01A (aliquot TCGA-CJ-6032-01A-11D-1669-08) from TCGA case TCGA-CJ-6032, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 63.8 years (23,310 days).
Specimen TCGA-CJ-6032-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f35bd5e-b264-4a57-85b6-86f289aeb2eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-6032-11A (Solid Tissue Normal), aliquot TCGA-CJ-6032-11A-01D-1669-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0cf357ec-7f54-40db-b807-9e609785bccf

The open-access MAF lists 49 somatic variants for this specimen: 37 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 11, Frame Shift Del 2, Nonsense Mutation 2, Frame Shift Ins 2, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.451A>T p.I151F | Missense Mutation (SNP) | VAF 60/152 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM125936, COSV56550461; called by muse, mutect2, varscan2
- VHL | c.452T>A p.I151N | Missense Mutation (SNP) | VAF 59/152 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1410322, CM994244, COSV56545117, COSV56548828, COSV56550478, COSV56564804; called by muse, mutect2, varscan2
- ABHD2 | c.876C>G p.S292R | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV61774049; called by muse, mutect2, varscan2
- AFDN | c.3145-2A>G p.X1049_splice | Splice Site (SNP) | VAF 26/87 reads (30%) | catalogued as COSV104417117, COSV60044772; called by muse, mutect2, varscan2
- APOB | c.10504G>T p.G3502C | Missense Mutation (SNP) | VAF 78/177 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs751352552, COSV51923431, COSV51935513; called by muse, mutect2, varscan2
- C12orf40 | c.410T>A p.M137K | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV61132575; called by muse, mutect2, varscan2
- CACNA1H | c.4093A>T p.N1365Y | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61990730; called by muse, mutect2, varscan2
- CNTN1 | c.2930G>A p.R977H | Missense Mutation (SNP) | VAF 70/270 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61637208; called by muse, mutect2, varscan2
- CUL9 | c.4746G>A p.M1582I | Missense Mutation (SNP) | VAF 82/312 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as COSV52728642; called by muse, mutect2, varscan2
- CYSLTR1 | c.854C>A p.A285E | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64820172, COSV64820982; called by muse, mutect2, varscan2
- EPPK1 | c.4410G>A p.W1470* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as COSV73261285; called by muse, mutect2, varscan2
- HTR1A | c.927C>A p.S309R | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV60500823; called by muse, mutect2, varscan2
- IGSF3 | c.710A>G p.Q237R | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.755); catalogued as COSV59590867; called by muse, mutect2, varscan2
- ITGA10 | c.601C>T p.Q201* | Nonsense Mutation (SNP) | VAF 27/108 reads (25%) | catalogued as rs782688752, COSV65197436; called by muse, mutect2, varscan2
- KCNK17 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.187); catalogued as COSV64685533; called by muse, mutect2, varscan2
- KIAA0319L | c.2602C>T p.R868W | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.328); catalogued as rs749736814, COSV57845785; called by muse, mutect2, varscan2
- KLHL34 | c.1000C>A p.Q334K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV65279355; called by muse, mutect2, varscan2
- KRTAP1-3 | c.11G>C p.C4S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs759358760, COSV60336115; called by muse, varscan2
- LIPE | c.2668G>A p.D890N | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.307); catalogued as COSV54922945; called by muse, mutect2, varscan2
- LTA | c.427C>G p.P143A | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV69304647; called by muse, mutect2, varscan2
- MAGI2 | c.1536G>T p.L512F | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV62660303, COSV62675007; called by muse, mutect2, varscan2
- MATN1 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.397); catalogued as rs781008601, COSV65650612; called by muse, mutect2, varscan2
- MTTP | c.803T>C p.M268T | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (0.81); PolyPhen benign (0.015); catalogued as rs146513720; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NAPB | c.205G>C p.A69P | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100986016, COSV65464506; called by muse, mutect2, varscan2
- OR1L1 | c.848G>C p.G283A (on ENST00000373686; = p.G233A on NM_001005236.3) | Missense Mutation (SNP) | VAF 67/243 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV58935616, COSV58935700, COSV58935724; called by muse, mutect2, varscan2
- PHC2 | c.1217C>A p.P406Q | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57103903; called by muse, mutect2, varscan2
- PSMA6 | c.74T>C p.V25A | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54837760; called by muse, mutect2, varscan2
- RXRB | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.526); catalogued as COSV59497031; called by muse, mutect2, varscan2
- TBCCD1 | c.440G>T p.R147I | Missense Mutation (SNP) | VAF 57/211 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as COSV58662184, COSV58662210; called by muse, mutect2, varscan2
- TENM2 | c.4933A>T p.M1645L (on ENST00000518659 / NM_001122679.2; = p.M1406L on NM_001080428.3) | Missense Mutation (SNP) | VAF 41/217 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV69130526; called by muse, mutect2, varscan2
- TKTL1 | c.20G>C p.R7T | Missense Mutation (SNP) | VAF 47/156 reads (30%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as COSV54213023; called by muse, mutect2, varscan2
- TRPC4 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.852); catalogued as rs140628205; called by muse, mutect2, varscan2
- ZNF528 | c.446A>G p.E149G | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV64619438; called by muse, mutect2, varscan2
- FAM13A | c.930_931insA p.R311Tfs*5 | Frame Shift Ins (INS) | VAF 57/209 reads (27%) | called by mutect2, pindel, varscan2
- HMGN2 | c.42del p.A15Qfs*3 | Frame Shift Del (DEL) | VAF 17/77 reads (22%) | called by mutect2, pindel, varscan2
- SLC4A1AP | c.2024_2026delinsTT p.S675Ifs*7 | Frame Shift Del (DEL) | VAF 54/195 reads (28%) | called by pindel, varscan2*
- TYR | c.1209dup p.H404Afs*18 | Frame Shift Ins (INS) | VAF 24/88 reads (27%) | called by mutect2, pindel, varscan2
- ABCC9 | c.3543A>T p.G1181= | Silent (SNP) | VAF 39/104 reads (38%) | catalogued as COSV53971748; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2052C>A p.A684= | Silent (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2
- ALKBH5 | c.1041C>T p.N347= | Silent (SNP) | VAF 38/145 reads (26%) | catalogued as COSV67686991; called by muse, mutect2, varscan2
- CIAO2A | c.183G>T p.V61= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as COSV55538452; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1347T>A p.I449= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as COSV62567900; called by muse, mutect2, varscan2
- FGD4 | c.1800T>G p.L600= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as COSV56783903; called by muse, mutect2, varscan2
- INTS11 | c.516T>G p.S172= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV60088319; called by muse, mutect2, varscan2
- MS4A6A | c.72A>G p.A24= | Silent (SNP) | VAF 69/242 reads (29%) | catalogued as COSV60618655; called by muse, mutect2, varscan2
- QSER1 | c.613C>T p.L205= (on ENST00000399302; = p.L334= on NM_001076786.3) | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as COSV67900600; called by muse, mutect2, varscan2
- SMAP2 | c.204T>A p.V68= | Silent (SNP) | VAF 32/89 reads (36%) | catalogued as COSV65532326; called by muse, mutect2, varscan2
- TRARG1 | c.414C>T p.N138= | Silent (SNP) | VAF 62/230 reads (27%) | catalogued as rs529434651, COSV61562779; called by muse, mutect2, varscan2
- FAM118A | c.522+346G>A | Intron (SNP) | VAF 21/51 reads (41%) | catalogued as rs775352664, COSV99343614; called by muse, mutect2, varscan2
